Somatic mutation profile of tumor specimen MP2PRT-PASTRS-TMP1-A (aliquot MP2PRT-PASTRS-TMP1-A-1-0-D-A81X-36) from MP2PRT case MP2PRT-PASTRS, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.0 years (1,088 days).
Specimen MP2PRT-PASTRS-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 255d5d78-cb4e-4e59-8d27-afb6652cc9ff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASTRS-NB1-B (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASTRS-NB1-B-1-0-D-A81X-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d4e374ff-6864-4826-a334-ecfa3a13e4fd

The open-access MAF lists 11 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 3, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC160 | c.581C>T p.T194M | Missense Mutation (SNP) | VAF 143/289 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as rs796949346, COSV66251606, COSV66252048; called by muse, mutect2, varscan2
- NTRK3 | c.1475C>T p.S492L | Missense Mutation (SNP) | VAF 178/421 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.533); catalogued as rs768882070, COSV58119879; called by muse, mutect2, varscan2
- POTEE | c.1651G>A p.G551R | Missense Mutation (SNP) | VAF 40/658 reads (6%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs747324485, COSV58238683; called by muse, mutect2
- IGLV4-69 | chr22:22031470 del TCACA | Missense Mutation (DEL) | VAF 100/207 reads (48%) | called by mutect2, pindel, varscan2
- OR5C1 | c.946G>A p.G316R | Missense Mutation (SNP) | VAF 121/278 reads (44%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- OTOGL | c.167A>C p.Q56P (on ENST00000547103; = p.Q47P on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/289 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.314); called by muse, mutect2
- FGD1 | c.1732T>C p.L578= | Silent (SNP) | VAF 36/610 reads (6%) | called by muse, mutect2
- MDC1 | c.2559C>T p.T853= | Silent (SNP) | VAF 294/703 reads (42%) | catalogued as COSV64524610; called by muse, mutect2, varscan2
- SLC4A4 | c.1092C>T p.H364= (on ENST00000264485 / NM_001098484.3; = p.H320= on NM_003759.4) | Silent (SNP) | VAF 102/277 reads (37%) | catalogued as rs759277095, COSV52629239; called by muse, varscan2
- MAEA | c.70-2298G>C | Intron (SNP) | VAF 190/468 reads (41%) | catalogued as rs902604618; called by muse, mutect2, varscan2
- SPOCK1 | c.*702C>T | 3'UTR (SNP) | VAF 50/150 reads (33%) | called by muse, mutect2, varscan2
